Gene-level copy-number profile of tumor specimen TCGA-F7-7848-01A from TCGA case TCGA-F7-7848, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.2 years (17,251 days).
Specimen TCGA-F7-7848-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a46e09d6-74e8-4a26-b8b5-9473ab372546.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-F7-7848-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a442209-5907-4e2d-aaf6-7476a018326f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 107; copy number 2: 17,055; copy number 3: 2,699; copy number 4: 33,948; copy number 5: 2,418; copy number 6: 2,425; copy number 8: 901; copy number 9: 114; copy number 10: 36; copy number 13: 40; copy number 14: 1; copy number 20: 12; copy number 21: 15; copy number 22: 7; copy number 37: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-F7-7848-01A-11D-2128-01): tumor purity 0.57, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 267 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:65,615,773–67,425,607, 113 genes, copy number 9–20 (within-gene range 2–20) (broad region; genes not listed).
- chr11:68,312,591–70,436,584, 58 genes, copy number 14–37 (within-gene range 8–37): LRP5, PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr12:18,080,869–21,176,895, 38 genes, copy number 9: RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1.
- chr12:115,263,170–116,389,471, 21 genes, copy number 13–22 (within-gene range 6–22): AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2, AC009803.2, AC009803.1, UBA52P7, RN7SL865P, AC009387.1, LINC02463, AC012157.1, AC012157.3, MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1, AC079384.2, AC079384.1.
- chr12:122,983,480–123,761,755, 36 genes, copy number 10 (within-gene range 6–10): PITPNM2, MIR4304, PITPNM2-AS1, AC026362.2, MPHOSPH9, AC073857.1, C12orf65, CDK2AP1, AC068768.1, RNA5SP375, SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2, SNRNP35, RILPL1, AC145423.1, AC145423.2, MIR3908, TMED2-DT, TMED2, DDX55, SNORA9B, EIF2B1, GTF2H3, AC117503.3, AC117503.2, TCTN2, AC117503.1, ATP6V0A2, AC117503.5, RPL27P12, AC117503.4.
- chr18:45,104,361–45,181,382, 1 gene, copy number 13: AC090376.1.

Autosomal genes at a single copy (total copy number 1): 107. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
